Somatic mutation profile of tumor specimen MMRF_2062_1_BM_CD138pos (aliquot MMRF_2062_1_BM_CD138pos_T1_KHS5U_L08106) from MMRF case MMRF_2062, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.9 years (22,978 days).
Specimen MMRF_2062_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2752cba-5cd9-42e4-a2d9-7f070cb9b828.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2062_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2062_1_PB_Whole_C2_KHS5U_L08107; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c13846b5-dade-4ace-a244-41b552c93232

The open-access MAF lists 162 somatic variants for this specimen: 62 protein-altering or splice-affecting, 15 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 45, Intron 26, Silent 15, 5'UTR 7, 5'Flank 5, Nonsense Mutation 4, 3'Flank 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 63/136 reads (46%) | catalogued as rs1393544920, COSV100483393, COSV58591239; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 114/287 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOL4 | c.289A>T p.M97L (on ENST00000352371 / NM_145660.2; = p.M94L on NM_030643.4) | Missense Mutation (SNP) | VAF 197/448 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs768195971; called by muse, mutect2, varscan2
- CDH8 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 152/341 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756831047, COSV104408092; called by muse, mutect2, varscan2
- CENPE | c.5527C>A p.Q1843K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs543654462; called by muse, mutect2, varscan2
- DMBT1 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 90/138 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs754405043; called by muse, mutect2, varscan2
- FBLN5 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969341; called by muse, mutect2
- GRIN2A | c.3376C>A p.P1126T | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.58); catalogued as rs767974762; called by muse, mutect2, varscan2
- HFM1 | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs751599543, COSV54032641; called by muse, mutect2, varscan2
- IGLV4-60 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs138271962; called by muse, mutect2, varscan2
- IGLV5-45 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs572586796; called by muse, mutect2, varscan2
- MRGPRF | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1373662578, COSV57995455; called by muse, mutect2, varscan2
- NUTM1 | c.3269C>G p.S1090* | Nonsense Mutation (SNP) | VAF 165/377 reads (44%) | catalogued as COSV100148993, COSV59217480; called by muse, mutect2, varscan2
- OSR1 | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55344987; called by muse, mutect2, varscan2
- PHOX2B | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV56929045; called by muse, mutect2, varscan2
- PIK3C2G | c.2905C>T p.Q969* (on ENST00000676171; = p.Q928* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 79/170 reads (46%) | catalogued as COSV56816769; called by muse, mutect2, varscan2
- PTPRM | c.2259C>A p.F753L | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); catalogued as rs749263983, COSV59848593; called by muse, mutect2, varscan2
- RYR1 | c.10505G>A p.R3502Q | Missense Mutation (SNP) | VAF 127/233 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs369422480; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORCS3 | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751676272; called by muse, mutect2, varscan2
- TDRD6 | c.3620A>C p.E1207A | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV60174934; called by muse, mutect2, varscan2
- TROAP | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV57743528; called by muse, mutect2, varscan2
- UACA | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100537695; called by muse, mutect2, varscan2
- UBC | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV60058588; called by muse, mutect2, varscan2
- WDR3 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1453018800; called by muse, mutect2, varscan2
- ABHD8 | c.930C>A p.L310= | Splice Region (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- ANKRD50 | c.4105C>A p.L1369I | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- API5 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CDCA2 | c.3028A>C p.T1010P | Missense Mutation (SNP) | VAF 76/81 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CEP120 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CEP41 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CLCN4 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, varscan2
- CSMD2 | c.6519C>A p.H2173Q | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CTSL | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- DCAF4L1 | c.156C>G p.S52R | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- DZIP1L | c.2072G>C p.G691A | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP15 | c.3646G>T p.D1216Y | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- HSD17B11 | c.111A>C p.E37D | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV2-70D | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 57/59 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGLV7-46 | c.47-2A>T p.X16_splice | Splice Site (SNP) | VAF 50/103 reads (49%) | called by muse, varscan2
- IGLV7-46 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, varscan2
- IGLV7-46 | c.226C>G p.H76D | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- IL6R | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQCA1 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1168A>T p.S390C (on ENST00000485419 / NM_001197113.1; = p.S314C on NM_014575.3) | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JAG1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 68/81 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KANK3 | c.2318C>G p.A773G | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KDM6B | c.4170C>G p.H1390Q | Missense Mutation (SNP) | VAF 111/236 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- KIF3B | c.924T>A p.N308K | Missense Mutation (SNP) | VAF 144/247 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOM1 | c.9_16del p.P4Sfs*8 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | called by mutect2, pindel, varscan2
- NBEAL2 | c.2453T>C p.L818P | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NHSL1 | c.4555A>G p.N1519D | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NRDE2 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PARD3 | c.559A>G p.S187G | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE4A | c.2069C>A p.P690Q (on ENST00000380702 / NM_001111307.2; = p.P451Q on NM_006202.3) | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PRKCH | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA3C | c.1082A>C p.H361P | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- SLC39A13 | c.407C>A p.A136D | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TARS1 | c.1512dup p.F505Ifs*12 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- TMEM161B | c.802A>C p.T268P | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TRIO | c.5019C>G p.N1673K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TRRAP | c.451-1G>A p.X151_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- ZNF550 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ALDOA | c.909T>A p.I303= (on ENST00000642816 / NM_001243177.4; = p.I249= on NM_184041.5) | Silent (SNP) | VAF 158/356 reads (44%) | called by muse, mutect2, varscan2
- DSCC1 | c.282C>T p.F94= | Silent (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- FFAR3 | c.735T>C p.H245= | Silent (SNP) | VAF 36/287 reads (13%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.66G>C p.V22= | Silent (SNP) | VAF 62/128 reads (48%) | catalogued as rs544203333; called by muse, varscan2
- IGLV5-45 | c.174G>A p.Q58= | Silent (SNP) | VAF 80/166 reads (48%) | catalogued as rs375850965; called by muse, varscan2
- LCE1F | c.228C>T p.C76= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- LRRC17 | c.561G>C p.G187= | Silent (SNP) | VAF 116/422 reads (27%) | called by muse, mutect2, varscan2
- LRRC47 | c.78G>A p.L26= | Silent (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- NOP56 | c.33G>A p.A11= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- NOS3 | c.36G>T p.G12= | Silent (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- PLD1 | c.2577A>G p.G859= | Silent (SNP) | VAF 48/85 reads (56%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.105C>G p.P35= | Silent (SNP) | VAF 66/154 reads (43%) | catalogued as rs768643816, COSV100868305; called by muse, mutect2
- TIMM50 | c.663C>T p.D221= | Silent (SNP) | VAF 89/181 reads (49%) | catalogued as rs1303238327, COSV100068093; called by muse, mutect2, varscan2
- TNXB | c.7332A>T p.L2444= (on ENST00000647633; = p.L2197= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- WDR26 | c.1797T>A p.T599= (on ENST00000414423 / NM_001379403.1; = p.T499= on NM_025160.7) | Silent (SNP) | VAF 79/193 reads (41%) | called by muse, mutect2, varscan2
- ACAN | c.2026+588G>A | Intron (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- ACTG1 | c.364-114G>A | Intron (SNP) | VAF 27/47 reads (57%) | catalogued as rs555229238; called by muse, mutect2, varscan2
- ACTR3B | c.*54C>T | 3'UTR (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.*1883C>G | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2
- ADAMTS3 | c.*1882C>A | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2
- AOPEP | c.1661+3452G>C | Intron (SNP) | VAF 16/32 reads (50%) | called by mutect2, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 74/159 reads (47%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BRWD1 | c.6572-3381T>C | Intron (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- BTBD3 | c.-351C>T | 5'UTR (SNP) | VAF 14/108 reads (13%) | catalogued as rs543474477; called by muse, mutect2, varscan2
- C11orf87 | c.*55C>A | 3'UTR (SNP) | VAF 372/798 reads (47%) | called by muse, varscan2
- C3 | c.3647-70G>C | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- C4orf17 | c.547-1593G>A | Intron (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- CCDC178 | c.1022+67A>C | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- CCDC6 | c.*3069G>A | 3'UTR (SNP) | VAF 10/146 reads (7%) | catalogued as rs1256116030; called by muse, mutect2
- CD244 | chr1:160830680 T>C | 3'Flank (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2
- CHIA | c.480+261G>A | Intron (SNP) | VAF 23/24 reads (96%) | catalogued as rs753143811; called by muse, mutect2, varscan2
- CIT | c.5577-46G>T | Intron (SNP) | VAF 64/134 reads (48%) | called by muse, mutect2, varscan2
- CLINT1 | c.1381-1048G>T | Intron (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- CPLX2 | c.*3468C>G | 3'UTR (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- DENND1B | c.*4251T>A | 3'UTR (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- DIP2B | c.*288T>C | 3'UTR (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*1499G>A | 3'UTR (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- FAM149B1 | c.*1440C>G | 3'UTR (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- FBN1 | c.164+682C>T | Intron (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- FBN2 | c.*1226A>C | 3'UTR (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- FBXO28 | c.*3055G>C | 3'UTR (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- FGG | c.532+22G>T | Intron (SNP) | VAF 53/140 reads (38%) | catalogued as rs756344422; called by muse, mutect2, varscan2
- FIGN | c.*1815T>C | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- FOXF1 | c.*374A>G | 3'UTR (SNP) | VAF 39/40 reads (98%) | catalogued as rs894766085; called by muse, mutect2, varscan2
- FOXK2 | c.1787-5469C>T | Intron (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- FOXP1 | c.*1304G>T | 3'UTR (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- GRIN2A | c.*287T>A | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- HOXC9 | c.*449A>G | 3'UTR (SNP) | VAF 39/94 reads (41%) | catalogued as rs915110822; called by muse, mutect2, varscan2
- HS2ST1 | c.*4388T>C | 3'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- IL1R1 | c.*1926C>T | 3'UTR (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- KIF21B | c.*74C>A | 3'UTR (SNP) | VAF 107/239 reads (45%) | called by muse, mutect2, varscan2
- KRT8 | c.594+18C>T | Intron (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- LCOR | c.332+11793A>G | Intron (SNP) | VAF 63/118 reads (53%) | called by muse, mutect2, varscan2
- LDLR | c.*1970_*1995del | 3'UTR (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- LYRM9 | c.*82A>G | 3'UTR (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- MAP4K4 | chr2:101891984 T>G | 3'Flank (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- MARK3 | c.1587-873T>C | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, varscan2
- MBP | c.*804G>C | 3'UTR (SNP) | VAF 11/247 reads (4%) | called by muse, mutect2
- MEPCE | c.*210A>C | 3'UTR (SNP) | VAF 58/95 reads (61%) | called by muse, mutect2, varscan2
- MLPH | c.111-42C>T | Intron (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- MRO | c.*6G>C | 3'UTR (SNP) | VAF 23/616 reads (4%) | called by muse, mutect2
- MS4A1 | c.*517G>C | 3'UTR (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- MTMR7 | c.-58G>A | 5'UTR (SNP) | VAF 35/35 reads (100%) | catalogued as rs538553312; called by muse, mutect2, varscan2
- NAA25 | c.283+9C>A | Intron (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- NLGN1 | c.*792A>T | 3'UTR (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- NNT | c.*2956T>C | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*9207C>A | 3'UTR (SNP) | VAF 36/142 reads (25%) | called by muse, mutect2, varscan2
- OR2P1P | chr6:29076508 C>G | 5'Flank (SNP) | VAF 69/149 reads (46%) | called by muse, mutect2, varscan2
- PAGR1 | c.-239C>T | 5'UTR (SNP) | VAF 73/194 reads (38%) | catalogued as rs895528230; called by muse, mutect2, varscan2
- PAPOLG | c.*1814C>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- PARD6G | c.*2327del | 3'UTR (DEL) | VAF 74/232 reads (32%) | catalogued as rs904784685; called by mutect2, varscan2
- PHTF2 | c.*1075C>T | 3'UTR (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- PIGB | chr15:55319207 C>T | 5'Flank (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*1349C>G | 3'UTR (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2
- PKN1 | c.2154-83G>A | Intron (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- POFUT1 | c.*923T>A | 3'UTR (SNP) | VAF 59/155 reads (38%) | called by muse, mutect2, varscan2
- PPCS | c.*23A>G | 3'UTR (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2, varscan2
- PRKCH | c.*18G>T | 3'UTR (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- PRPF3 | c.277-45C>T | Intron (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- RAB27B | c.*2016G>A | 3'UTR (SNP) | VAF 43/159 reads (27%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891178 ins T | 5'Flank (INS) | VAF 62/90 reads (69%) | called by mutect2, pindel, varscan2
- RPGR | c.2520+1216G>C | Intron (SNP) | VAF 58/59 reads (98%) | called by muse, mutect2, varscan2
- SFXN1 | c.*1487C>T | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- SGCZ | c.-527del | 5'UTR (DEL) | VAF 36/52 reads (69%) | catalogued as rs80131151; called by mutect2, pindel, varscan2
- SHE | c.1302-381G>T | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- SLC13A3 | c.*1235C>T | 3'UTR (SNP) | VAF 8/177 reads (5%) | catalogued as rs946862276; called by muse, mutect2
- SLC1A7 | c.432-2457G>T | Intron (SNP) | VAF 92/209 reads (44%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1211-1874G>T | Intron (SNP) | VAF 65/130 reads (50%) | called by muse, mutect2, varscan2
- SMC4 | chr3:160400316 del GACGAAAGCGGGCGGCGAGTCGCCAGTTAGTCTTCACCG | 5'Flank (DEL) | VAF 77/391 reads (20%) | called by mutect2, pindel*
- SRPK1 | c.*1545T>G | 3'UTR (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- STIMATE | c.427+2272G>C | Intron (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- STK17A | c.-125G>A | 5'UTR (SNP) | VAF 21/47 reads (45%) | called by mutect2, varscan2
- TM9SF4 | c.*1060T>C | 3'UTR (SNP) | VAF 82/254 reads (32%) | called by muse, mutect2, varscan2
- TRGV11 | c.-111del | 5'UTR (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- TRGV11 | c.-112T>A | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- TRPM8 | c.*341A>T | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- TSPAN15 | c.735+22A>T | Intron (SNP) | VAF 56/126 reads (44%) | called by muse, mutect2, varscan2
- USP22 | c.*467G>A | 3'UTR (SNP) | VAF 64/178 reads (36%) | called by muse, mutect2, varscan2
- ZMAT3 | c.*491A>G | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- ZNF831 | c.*40T>G | 3'UTR (SNP) | VAF 100/101 reads (99%) | catalogued as COSV100926059; called by muse, varscan2
